Surgical pathology report (de-identified scan), TCGA case TCGA-AJ-A23O, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site International Genomics Conosrtium, specimen TCGA-AJ-A23O-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3

Carcinoma, endometrioid, NOS 8380/3

Site: endometrium c54.1 in 4/19/11

✓ Surgical Pathology

DEPARTMENT OF PATHOLOGY

PATIENT: [REDACTED] SPECIMEN: [REDACTED]
BIRTHDATE: [REDACTED] AGE: Y SEX: F
MRN: [REDACTED] Rm #: [REDACTED] PHYSICIAN: [REDACTED]
PROCEDURE DATE: [REDACTED] RECEIVED DATE: [REDACTED] REPORT DATE: [REDACTED]

COPY TO:

Pre-Op Diagnosis
Endometrial cancer
Post-Op Diagnosis
Same

Clinical History

Nothing indicated on requisition

Gross Description:

Four parts

Container labeled "[REDACTED] 1 - left pelvic lymph nodes" are 6.0 x 4.8 x 2.6 cm of tan yellow fibroadipose tissue fragments which on palpation and sectioning reveal several poorly defined tan yellow to brown nodules up to 3.0 cm in greatest dimension. On sectioning the largest nodule is a grossly fat cut surface. The individual nodules are bisected and submitted labeled "A through C" while whole smaller nodules are submitted labeled "D."

Container labeled "[REDACTED] 2 - right pelvic lymph nodes" are 5.0 x 4.0 x 1.7 cm of tan yellow fibroadipose tissue fragments which on palpation and sectioning reveal several poorly defined tan yellow to brown nodules up to 3.3 cm. On sectioning the largest nodule has a fleshy and fatty cut surface. The individual nodules are bisected and submitted labeled "A and D" while whole smaller nodules are submitted labeled "C."

Container labeled "[REDACTED] 3 - uterus, cervix, bilateral tubes and ovaries" is a previously anteriorly opened moderately distorted uterus with attached cervix and bilateral adnexa. The uterus and cervix together weigh 65 grams and on reconstruction measure approximately 8.0 x 5.5 x 4.0 cm. The cervix has a wrinkled gray tan ectocervical mucosa. The os is patent. The uterine canal sounds to a depth of approximately 6.7 cm. The endocervical canal is lined by trabeculated gray tan mucosa. The uterine serosa is smooth and tan brown. The myometrium is up to 1.6 cm and is tan

Reviewed	Date Reviewed: 4/19/11	

[page 2 of 3]
brown and fibrotic. The majority of the endometrial canal is occupied by friable granular gray tan to brown papilliferous lesion occupying an area overall 4.6 x 3.5 cm which includes both the anterior and posterior aspects as well as both lateral aspects in the fundus. On sectioning this has a gritty gray tan fibrotic cut surface grossly extending into the myometrium to within 0.3 cm of the anterior serosa. In this area the lesion measures 1.8 cm in thickness. The lesion extends grossly to within 0.3 cm of the posterior serosa as well. This is seen within 0.4 cm of the fundic serosa and within 0.2 cm of the right lateral aspect. The small amount of parametrial soft tissue on each side shows no nodularity or gross lesions.

The left fallopian tube is 4.6 x 0.5 x 0.5 cm. The right fallopian tube is 5.5 x 0.5 x 0.5 cm. Each has a smooth tan brown serosa with a tan wall and a pinpoint lumen. The left ovary is 2.0 x 1.2 x 0.8 cm and has a lobular gray tan outer surface with a mottled gray tan fibrotic cut surface. The right ovary is 2.0 x 1.0 x 0.8 cm and has a lobular gray tan to brown outer surface with a mottled gray tan fibrotic cut surface having a few thin walled clear fluid filled cystic structures with smooth inner linings measuring up to 0.3 cm. Also received in the same container are two tissue cassettes each labeled " ". Representative sections are submitted labeled as follows: A - anterior cervix; B - posterior cervix; C - lower uterine segment and shaved posterior serosa; D and E - anterior endomyometrium; F and G - posterior endomyometrium; H and I - left lateral endomyometrium; J and K - right lateral endomyometrium; L and M - fundic endomyometrium; N - left parametrium; O - right parametrium; P - left adnexa; Q - right adnexa.

Container labeled " " 4 - right aortic node" is a 3.6 x 1.5 x 1.0 cm aggregate of tan yellow fibroadipose tissue fragments which on palpation and sectioning reveal a few poorly defined tan yellow nodular regions up to 0.8 cm. The nodular tissue is submitted in a single cassette.

Microscopic Description:

Slides reviewed.

Final Diagnosis

Left pelvic lymph node dissection:

Nine benign hyperplastic regional lymph nodes (0/9).

Right pelvic lymph node dissection:

Six benign hyperplastic regional lymph nodes (0/6).

Hysterectomy:

~~Carcinoma of endometrium~~

Tumor characteristics:

Histologic type: ~~Endometrioid carcinoma~~

Grade: Poorly differentiated, WHO Grade III.

Location: Uterine fundus in general.

Extent of invasion: Tumor invades more than one-half of the myometrium. Maximal thickness of myometrial invasion is 13 mm into a 16 mm thick myometrium.

Extension of tumor: Does not involve endocervix or cervical stroma.

Lymphovascular space invasion: Present.

Surgical margin status:

Cervical margin: Negative.

Left parametrial margin: Negative.

Right parametrial margin: Negative.

Lymph node status (utilizing all specimens submitted).

[page 3 of 3]
Sites: Bilateral pelvic, right aortic.

Number of lymph nodes examined: 19

Number of lymph nodes containing metastatic carcinoma: 0 (0/19)

Other:

Cervix/endocervix: No pathologic diagnosis.

Endometrium: Complex hyperplasia with atypia.

Myometrium: No additional abnormalities.

Uterine serosa-bilateral fallopian tubes and ovaries:

Adhesions. SPC-A PAS 9

Right aortic lymph node dissection:

Four benign hyperplastic regional lymph nodes (0/4).

Stage: pT1b, N0

CPT: 88307 x 3, 88309

Comments

This test has been finalized at the [REDACTED] Campus.

<Sign Out Dr. Signature>

[REDACTED], M.D.

Source: NCI Genomic Data Commons file 784f3e58-b436-490a-b29f-af6df7bd55f4 (TCGA-AJ-A23O.4D477218-A4D1-4940-AEF5-D8F46931594C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).